Somatic mutation profile of tumor specimen C3L-01355-02 (aliquot CPT0083580006) from CPTAC case C3L-01355, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 55.9 years (20,413 days).
Specimen C3L-01355-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15cc1205-570c-4988-a5aa-8d6869c370e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01355-31 (Blood Derived Normal), aliquot CPT0081810002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2153d8ca-9588-41cc-a943-70adef4ef110

The open-access MAF lists 51 somatic variants for this specimen: 31 protein-altering or splice-affecting, 11 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 11, Intron 5, 3'UTR 3, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.1647T>A p.N549K | Missense Mutation (SNP) | VAF 150/262 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913476, COSV60638757, COSV60639738; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKRD30B | c.2753C>A p.P918H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99080465; called by muse, mutect2, varscan2
- ARID1A | c.5000dup p.E1668Gfs*30 | Frame Shift Ins (INS) | VAF 32/138 reads (23%) | catalogued as COSV61389037; called by mutect2, pindel
- ARID1A | c.5942G>A p.C1981Y | Missense Mutation (SNP) | VAF 22/438 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61373894; called by muse, mutect2
- BMPR2 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 35/306 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as CM1513949, COSV101001676; called by muse, mutect2, varscan2
- CDH4 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV64672772; called by muse, mutect2, varscan2
- CREBBP | c.4327C>T p.R1443C | Missense Mutation (SNP) | VAF 76/293 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52114466; called by muse, varscan2
- CTCF | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50467714; called by muse, mutect2, varscan2
- DEGS1 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs962301027; called by muse, mutect2, varscan2
- DSG2 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 73/269 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.446); catalogued as rs550400909; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELMO3 | c.1717A>G p.I573V (on ENST00000652269; = p.I520V on NM_024712.5) | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1042140249; called by muse, mutect2
- GBA | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 160/586 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs760307559, HM971756; called by muse, mutect2, varscan2
- KHDC1L | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs1182759945, COSV64893344; called by muse, mutect2, varscan2
- PIK3C2A | c.3776G>A p.R1259Q | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs766891920, COSV104381540; called by muse, mutect2, varscan2
- PLXNB2 | c.4700C>T p.P1567L | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.55); catalogued as rs368368664; called by muse, mutect2, varscan2
- PRSS35 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 55/226 reads (24%) | catalogued as rs773975931, COSV63800668; called by muse, mutect2, varscan2
- PTEN | c.143A>G p.N48S | Missense Mutation (SNP) | VAF 57/103 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV64291337, COSV64303263; called by muse, mutect2, varscan2
- RELT | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 103/336 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs775696442, COSV50362308, COSV50362358; called by muse, mutect2, varscan2
- ZYG11A | c.1903A>C p.I635L | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1031923920; called by muse, mutect2, varscan2
- AL121899.2 | c.1289A>G p.K430R | Missense Mutation (SNP) | VAF 145/512 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1A | c.3210del p.N1070Kfs*23 | Frame Shift Del (DEL) | VAF 74/210 reads (35%) | called by mutect2, pindel, varscan2
- BBC3 | c.69G>T p.W23C | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD9 | c.943A>G p.R315G | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAH14 | c.5440G>A p.E1814K (on ENST00000445597; = p.E2219K on NM_001367479.1) | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ELOA | c.1610G>C p.R537P | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GPC4 | c.1597C>A p.R533S | Missense Mutation (SNP) | VAF 113/369 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIRREL3 | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PKD1 | c.7918G>A p.A2640T | Missense Mutation (SNP) | VAF 232/879 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PTPN23 | c.4420A>G p.I1474V | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCGB1D2 | c.218A>C p.K73T | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); called by muse, mutect2
- ACACA | c.2181C>G p.P727= | Silent (SNP) | VAF 55/217 reads (25%) | called by muse, mutect2, varscan2
- CALHM2 | c.390T>C p.C130= | Silent (SNP) | VAF 119/437 reads (27%) | catalogued as rs534148574; called by muse, mutect2, varscan2
- FASTKD1 | c.1824G>A p.L608= | Silent (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- GRIK5 | c.564G>A p.L188= | Silent (SNP) | VAF 51/207 reads (25%) | catalogued as COSV53478032; called by muse, mutect2, varscan2
- KRT18 | c.1099C>T p.L367= | Silent (SNP) | VAF 139/558 reads (25%) | called by muse, mutect2, varscan2
- KRT74 | c.330G>A p.G110= | Silent (SNP) | VAF 106/339 reads (31%) | called by muse, mutect2, varscan2
- LSS | c.2001C>T p.I667= | Silent (SNP) | VAF 83/278 reads (30%) | catalogued as rs750802193; called by muse, mutect2, varscan2
- NYX | c.192G>A p.A64= | Silent (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- RAB5C | c.462C>T p.D154= | Silent (SNP) | VAF 32/131 reads (24%) | catalogued as rs140472226; called by muse, mutect2, varscan2
- TRIM35 | c.948C>T p.S316= | Silent (SNP) | VAF 40/124 reads (32%) | catalogued as rs139383740; called by muse, mutect2, varscan2
- WNT9B | c.180G>A p.L60= | Silent (SNP) | VAF 31/92 reads (34%) | called by muse, mutect2, varscan2
- BRCA1 | c.*512T>C | 3'UTR (SNP) | VAF 61/237 reads (26%) | called by muse, mutect2, varscan2
- CCR2 | c.941+75C>G | Intron (SNP) | VAF 61/202 reads (30%) | catalogued as rs778974525; called by muse, mutect2, varscan2
- GABBR1 | c.*539G>A | 3'UTR (SNP) | VAF 33/128 reads (26%) | catalogued as rs979747254, COSV100589726; called by muse, mutect2, varscan2
- LRRC71 | c.1563+49G>A | Intron (SNP) | VAF 115/413 reads (28%) | called by muse, mutect2, varscan2
- NFATC2IP | c.460+80C>T | Intron (SNP) | VAF 21/59 reads (36%) | called by muse, varscan2
- NRG1 | chr8:31639407 C>T | 5'Flank (SNP) | VAF 54/326 reads (17%) | called by muse, mutect2, varscan2
- SLC25A41 | c.364-385G>T | Intron (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2
- SYT14 | c.*168G>T | 3'UTR (SNP) | VAF 35/122 reads (29%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+5468C>T | Intron (SNP) | VAF 20/68 reads (29%) | catalogued as rs1560657196; called by muse, mutect2, varscan2
